Somatic mutation profile of cancer-model specimen HCM-CSHL-0433-C24-85A (3D Organoid; aliquot HCM-CSHL-0433-C24-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0433-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.1 years (19,015 days).
Specimen HCM-CSHL-0433-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7557dac3-ea4c-45b7-9bd6-10c551cba05a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0433-C24-11A (Solid Tissue Normal), aliquot HCM-CSHL-0433-C24-11A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2da93a17-e1af-4cbb-b23f-25f7a701ca96

The open-access MAF lists 76 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 10, Intron 6, 3'UTR 5, Nonsense Mutation 2, Splice Site 2, 5'UTR 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 141/398 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4774C>T p.R1592* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as rs1057518410, COSV57432438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALOXE3 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV59076749; called by muse, mutect2, varscan2
- ARHGAP24 | c.180+1G>A p.X60_splice | Splice Site (SNP) | VAF 39/168 reads (23%) | catalogued as rs746812851, COSV101232969; called by muse, mutect2, varscan2
- ARSI | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 105/181 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754848958; called by muse, mutect2, varscan2
- ATP13A1 | c.3307G>A p.V1103I | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.699); catalogued as rs763580040, COSV99179598; called by muse, mutect2, varscan2
- CACTIN | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 157/289 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV50266552; called by muse, mutect2, varscan2
- DDX11 | c.2209C>T p.Q737* (on ENST00000545668 / NM_152438.2; = p.Q687* on NM_004399.3) | Nonsense Mutation (SNP) | VAF 203/538 reads (38%) | catalogued as rs757776704; called by muse, mutect2, varscan2
- DMRTC2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV99523521; called by muse, mutect2, varscan2
- FXN | c.15A>C p.K5N (on ENST00000377270; = p.K80N on NM_000144.5) | Missense Mutation (SNP) | VAF 305/305 reads (100%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs1169387979; called by muse, mutect2, varscan2
- HMOX2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs1298327866; called by muse, mutect2, varscan2
- KCNJ5 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57963912; called by muse, mutect2, varscan2
- KIF21B | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754732012, COSV59760556; called by muse, mutect2, varscan2
- LYST | c.6775G>A p.V2259I | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs773927032; called by muse, mutect2, varscan2
- MYT1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs903442892, COSV100114387, COSV60513530; called by muse, mutect2, varscan2
- NAP1L3 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV59076384; called by muse, mutect2, varscan2
- NCOA1 | c.3190G>A p.G1064R | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56055792; called by muse, mutect2, varscan2
- PALLD | c.2902G>A p.V968I (on ENST00000505667 / NM_001166108.2; = p.V951I on NM_016081.4) | Missense Mutation (SNP) | VAF 125/232 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs551420048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA9 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV100969368; called by muse, mutect2, varscan2
- PSG1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 188/390 reads (48%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.623); catalogued as rs150536125; called by muse, varscan2
- SMAD4 | c.1089T>G p.C363W | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747670; called by muse, mutect2, varscan2
- SPATC1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs572315628, COSV66299115; called by muse, mutect2, varscan2
- STAT3 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 294/660 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52890394; called by muse, mutect2, varscan2
- UBP1 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 30/30 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs770784996; called by muse, mutect2
- ZNF217 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs372777442; called by muse, mutect2, varscan2
- ZNF438 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467708296; called by muse, mutect2, varscan2
- ZNF804A | c.2908C>G p.L970V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV56473326; called by muse, mutect2, varscan2
- ACTRT1 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ADAMTS13 | c.3968G>A p.G1323E | Missense Mutation (SNP) | VAF 356/357 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ADCY10 | c.394A>C p.T132P | Missense Mutation (SNP) | VAF 272/542 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ARL6 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHERP | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COL4A6 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2
- CPE | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 123/264 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- HMSD | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT tolerated (0.9); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IL2RB | c.1607A>T p.Y536F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JARID2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 109/162 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- KRTAP9-3 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 245/518 reads (47%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MAIP1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MED24 | c.672-2A>G p.X224_splice | Splice Site (SNP) | VAF 175/342 reads (51%) | called by muse, mutect2, varscan2
- MTMR11 | c.1825C>T p.L609F (on ENST00000439741 / NM_001145862.2; = p.L537F on NM_181873.3) | Missense Mutation (SNP) | VAF 178/359 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEA | c.6898T>G p.L2300V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NGEF | c.1103G>A p.S368N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OR8D4 | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- P4HTM | c.1422_1423dup p.A475Gfs*59 (on ENST00000383729 / NM_177939.3; = p.A536Gfs*59 on NM_177938.2) | Frame Shift Ins (INS) | VAF 157/398 reads (39%) | called by mutect2, pindel, varscan2
- RC3H1 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STYXL2 | c.1457A>T p.E486V | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM51 | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TUBB4B | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- UTRN | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ZNF548 | c.1464A>C p.R488S | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF729 | c.2043G>T p.K681N | Missense Mutation (SNP) | VAF 145/327 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, varscan2
- ABCA3 | c.1902G>A p.K634= | Silent (SNP) | VAF 135/266 reads (51%) | called by muse, mutect2, varscan2
- CLCN2 | c.126C>T p.R42= | Silent (SNP) | VAF 137/286 reads (48%) | called by muse, mutect2, varscan2
- GAD2 | c.114C>T p.G38= | Silent (SNP) | VAF 113/248 reads (46%) | catalogued as rs1235686175, COSV99394122; called by muse, mutect2, varscan2
- KCNG4 | c.642G>A p.P214= | Silent (SNP) | VAF 124/280 reads (44%) | catalogued as rs752941174; called by muse, mutect2
- NACAD | c.414G>A p.A138= | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as rs764877585; called by muse, mutect2, varscan2
- OR2T2 | c.660G>A p.T220= | Silent (SNP) | VAF 316/653 reads (48%) | catalogued as rs770828092, COSV61617719; called by muse, varscan2
- RFPL4B | c.201C>T p.S67= | Silent (SNP) | VAF 134/135 reads (99%) | catalogued as rs112616941; called by muse, mutect2, varscan2
- TP53BP1 | c.5412A>G p.L1804= | Silent (SNP) | VAF 92/176 reads (52%) | catalogued as rs1169949685; called by muse, mutect2, varscan2
- URGCP | c.2616G>A p.K872= (on ENST00000453200 / NM_001077663.3; = p.K863= on NM_017920.4) | Silent (SNP) | VAF 142/261 reads (54%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1875C>T p.N625= | Silent (SNP) | VAF 189/350 reads (54%) | catalogued as rs566297803, COSV60089798; called by muse, mutect2, varscan2
- CD81 | c.561+45G>A | Intron (SNP) | VAF 125/261 reads (48%) | catalogued as rs368913200; called by muse, mutect2, varscan2
- CHRNA7 | c.350+394A>G | Intron (SNP) | VAF 110/246 reads (45%) | catalogued as rs986078370; called by muse, mutect2, varscan2
- CPN1 | c.*20C>A | 3'UTR (SNP) | VAF 167/386 reads (43%) | called by muse, mutect2, varscan2
- FAS | c.*989A>T | 3'UTR (SNP) | VAF 91/164 reads (55%) | called by muse, mutect2, varscan2
- FLT4 | c.2648-92C>T | Intron (SNP) | VAF 70/147 reads (48%) | catalogued as rs1438549116; called by muse, mutect2, varscan2
- FOXP2 | c.*1953A>G | 3'UTR (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- H3-2 | c.*94G>A | 3'UTR (SNP) | VAF 223/712 reads (31%) | called by muse, mutect2, varscan2
- MIR544A | n.54G>C | RNA (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- NKX2-1 | c.-23C>T | 5'UTR (SNP) | VAF 104/221 reads (47%) | called by muse, mutect2, varscan2
- OBP2A | c.*55G>A | 3'UTR (SNP) | VAF 30/104 reads (29%) | catalogued as rs200533613; called by muse, mutect2, varscan2
- RGS11 | c.318+306C>T | Intron (SNP) | VAF 24/62 reads (39%) | called by mutect2, varscan2
- TBX5 | c.-25G>A | 5'UTR (SNP) | VAF 417/418 reads (100%) | catalogued as rs748222016; called by muse, mutect2, varscan2
- TRPV2 | c.2115-43C>T | Intron (SNP) | VAF 54/54 reads (100%) | catalogued as rs370803898; called by muse, mutect2, varscan2
- WWP1 | c.2132+19G>A | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs930854048; called by muse, mutect2, varscan2
